Somatic mutation profile of tumor specimen HCM-CSHL-0461-D12-86A (aliquot HCM-CSHL-0461-D12-86A-01D-A85C-36) from HCMI case HCM-CSHL-0461-D12, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Serrated adenoma; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage 0; Tumor grade: GX; Age at diagnosis: 54.7 years (19,976 days).
Specimen HCM-CSHL-0461-D12-86A: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Premalignant; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a47e51c1-2c62-40fb-9ff2-54b391fbd1e2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0461-D12-10A (Blood Derived Normal), aliquot HCM-CSHL-0461-D12-10A-01D-A78U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9158a3ac-33cc-494e-b4c3-0e4c7239bb5a

The open-access MAF lists 76 somatic variants for this specimen: 54 protein-altering or splice-affecting, 19 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 19, Nonsense Mutation 5, Frame Shift Ins 3, Intron 2, Splice Region 2, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.847C>T p.R283* | Nonsense Mutation (SNP) | VAF 161/322 reads (50%) | catalogued as rs786201856, CM920030, COSV57325157; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 284/638 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- SMAD4 | c.692dup p.S232Qfs*3 | Frame Shift Ins (INS) | VAF 276/480 reads (58%) | catalogued as rs377767334, COSV61691229; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SMAD4 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 251/847 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs377767347, CM004254, CM100519, COSV61684056, COSV61686014, COSV61689167; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3415C>T p.R1139W | Missense Mutation (SNP) | VAF 307/606 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs145388431; called by muse, mutect2, varscan2
- APC | c.4243dup p.S1415Kfs*8 | Frame Shift Ins (INS) | VAF 208/452 reads (46%) | catalogued as COSV57328975; called by mutect2, pindel, varscan2
- BIRC7 | c.787G>A p.V263I (on ENST00000217169 / NM_139317.3; = p.V245I on NM_022161.4) | Missense Mutation (SNP) | VAF 467/945 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs1211741916, COSV53903059; called by muse, mutect2, varscan2
- CSMD2 | c.8248G>A p.G2750S | Missense Mutation (SNP) | VAF 251/518 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as rs144107939; called by muse, mutect2, varscan2
- DNAH5 | c.1852C>T p.R618* | Nonsense Mutation (SNP) | VAF 284/571 reads (50%) | catalogued as rs778780449, COSV54220884; called by muse, mutect2, varscan2
- DNHD1 | c.13634C>T p.P4545L | Missense Mutation (SNP) | VAF 445/902 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV54435909; called by muse, mutect2, varscan2
- FLG | c.1444C>A p.H482N | Missense Mutation (SNP) | VAF 311/699 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as rs745468641; called by muse, mutect2, varscan2
- GRIN2A | c.2083C>T p.R695W | Missense Mutation (SNP) | VAF 264/580 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58034105; called by muse, mutect2, varscan2
- INTS6 | c.1936G>A p.G646R | Missense Mutation (SNP) | VAF 244/538 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.221); catalogued as rs1372857363, COSV60878750; called by muse, mutect2, varscan2
- LILRA4 | c.1097G>A p.R366H | Missense Mutation (SNP) | VAF 484/979 reads (49%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs139101339; called by muse, mutect2, varscan2
- MINK1 | c.3929C>T p.S1310L | Missense Mutation (SNP) | VAF 262/554 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs774790111; called by muse, mutect2, varscan2
- NOL4 | c.449C>A p.A150E | Missense Mutation (SNP) | VAF 188/634 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52345895; called by muse, varscan2
- NPBWR2 | c.842T>C p.V281A | Missense Mutation (SNP) | VAF 525/1094 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as COSV63899936; called by muse, mutect2, varscan2
- NT5C3A | c.217G>C p.G73R (on ENST00000610140 / NM_001374335.1; = p.G39R on NM_016489.13) | Missense Mutation (SNP) | VAF 198/403 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.798); catalogued as COSV54238498; called by muse, mutect2, varscan2
- OTOF | c.1955G>A p.R652Q | Missense Mutation (SNP) | VAF 328/737 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.024); catalogued as rs142370721; called by muse, mutect2, varscan2
- RNFT2 | c.448G>T p.A150S | Missense Mutation (SNP) | VAF 465/1016 reads (46%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.992); catalogued as rs148512260, COSV57487003; called by muse, mutect2, varscan2
- ROBO2 | c.1478C>G p.S493* | Nonsense Mutation (SNP) | VAF 183/352 reads (52%) | catalogued as COSV100163019, COSV59950025; called by muse, mutect2, varscan2
- SETD1B | c.4409C>T p.T1470M | Missense Mutation (SNP) | VAF 523/1057 reads (49%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.584); catalogued as rs1490141875; called by muse, mutect2, varscan2
- SLC6A11 | c.874C>T p.R292W | Missense Mutation (SNP) | VAF 211/453 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757531916; called by muse, mutect2, varscan2
- STAG1 | c.640C>G p.Q214E | Missense Mutation (SNP) | VAF 209/440 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as COSV99365835; called by muse, mutect2, varscan2
- STRC | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 346/1451 reads (24%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.998); catalogued as rs1399374103; called by muse, mutect2, varscan2
- SULF1 | c.1727G>A p.R576H | Missense Mutation (SNP) | VAF 352/750 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs758690728, COSV52674097; called by muse, mutect2, varscan2
- THOC5 | c.854C>T p.T285M | Missense Mutation (SNP) | VAF 222/467 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.372); catalogued as rs141199207; called by muse, varscan2
- TPCN2 | c.367G>A p.G123S | Missense Mutation (SNP) | VAF 413/862 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs541105565; called by muse, mutect2, varscan2
- TRIOBP | c.7078C>T p.R2360C (on ENST00000644935 / NM_001039141.3; = p.R647C on NM_007032.5) | Missense Mutation (SNP) | VAF 193/452 reads (43%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.036); catalogued as rs371230470; called by muse, mutect2, varscan2
- UBE4B | c.2581G>A p.A861T (on ENST00000343090 / NM_001105562.3; = p.A732T on NM_006048.5) | Missense Mutation (SNP) | VAF 172/391 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.025); catalogued as rs147329205, COSV53532772; called by muse, varscan2
- ZFP36L2 | c.303dup p.K102* | Frame Shift Ins (INS) | VAF 256/679 reads (38%) | catalogued as COSV56700443; called by pindel, varscan2
- ZNF469 | c.11483G>A p.R3828H (on ENST00000437464; = p.R3856H on NM_001367624.2) | Missense Mutation (SNP) | VAF 473/999 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs187075195, COSV71259370; called by muse, mutect2, varscan2
- ZNF628 | c.2726C>T p.A909V | Missense Mutation (SNP) | VAF 429/910 reads (47%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs920009714; called by muse, mutect2, varscan2
- ZNF878 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 337/685 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as rs777626762, COSV72155963; called by muse, mutect2, varscan2
- CTSF | c.97G>C p.G33R | Missense Mutation (SNP) | VAF 516/1040 reads (50%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2
- DOCK2 | c.3627T>C p.N1209= | Splice Region (SNP) | VAF 153/306 reads (50%) | called by muse, mutect2, varscan2
- DUSP5 | c.148G>T p.V50L | Missense Mutation (SNP) | VAF 532/1142 reads (47%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- FMNL2 | c.951+5G>A | Splice Region (SNP) | VAF 124/283 reads (44%) | called by muse, mutect2, varscan2
- ITGA7 | c.1360A>T p.K454* (on ENST00000555728; = p.K410* on NM_002206.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 188/438 reads (43%) | called by muse, varscan2
- KANK2 | c.661_662insTGTAGCTCTCGGTGCTCCAGG p.Q220_E221insV* | Nonsense Mutation (INS) | VAF 85/424 reads (20%) | called by mutect2, varscan2*
- MYO1F | c.101C>A p.A34D | Missense Mutation (SNP) | VAF 276/594 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- PPP1R7 | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 189/416 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- PPP4R3C | c.281G>C p.W94S | Missense Mutation (SNP) | VAF 208/209 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRELID3B | c.37C>G p.P13A | Missense Mutation (SNP) | VAF 140/297 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- SF3B4 | c.1171C>G p.P391A | Missense Mutation (SNP) | VAF 515/948 reads (54%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- SIN3A | c.431A>G p.Y144C | Missense Mutation (SNP) | VAF 191/392 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMC3 | c.350+1G>C p.X117_splice | Splice Site (SNP) | VAF 148/362 reads (41%) | called by muse, varscan2
- STYK1 | c.1030A>G p.I344V | Missense Mutation (SNP) | VAF 203/410 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TIMMDC1 | c.208A>G p.I70V | Missense Mutation (SNP) | VAF 213/416 reads (51%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, varscan2
- TMEM87A | c.836A>T p.E279V | Missense Mutation (SNP) | VAF 234/463 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TSHZ2 | c.508C>A p.Q170K | Missense Mutation (SNP) | VAF 31/592 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- TTN | c.4370C>T p.P1457L (on ENST00000591111; = p.P1411L on NM_003319.4) | Missense Mutation (SNP) | VAF 194/429 reads (45%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZGRF1 | c.5272C>A p.P1758T | Missense Mutation (SNP) | VAF 296/658 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); called by muse, varscan2
- ZNF827 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 297/640 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- A2M | c.1641T>A p.P547= | Silent (SNP) | VAF 272/567 reads (48%) | called by muse, mutect2, varscan2
- BORCS5 | c.507G>C p.L169= | Silent (SNP) | VAF 272/577 reads (47%) | called by muse, mutect2, varscan2
- CHRM3 | c.1752C>T p.R584= | Silent (SNP) | VAF 172/407 reads (42%) | catalogued as rs201601302, COSV55085033; called by muse, mutect2, varscan2
- CSF1R | c.327C>T p.N109= | Silent (SNP) | VAF 235/509 reads (46%) | catalogued as rs781316589; called by muse, mutect2, varscan2
- DELE1 | c.966C>T p.C322= | Silent (SNP) | VAF 225/512 reads (44%) | called by muse, mutect2, varscan2
- FAT4 | c.10503C>T p.T3501= | Silent (SNP) | VAF 304/586 reads (52%) | called by muse, mutect2, varscan2
- FAT4 | c.13617C>A p.P4539= | Silent (SNP) | VAF 304/670 reads (45%) | called by muse, mutect2
- FMOD | c.441C>A p.G147= | Silent (SNP) | VAF 264/641 reads (41%) | called by muse, mutect2, varscan2
- GPR174 | c.157C>A p.R53= | Silent (SNP) | VAF 262/370 reads (71%) | catalogued as COSV52133979; called by muse, mutect2, varscan2
- ITGA7 | c.1359G>T p.G453= (on ENST00000555728; = p.G409= on NM_002206.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 188/438 reads (43%) | called by muse, varscan2
- MNT | c.930G>T p.L310= | Silent (SNP) | VAF 317/856 reads (37%) | called by muse, mutect2, varscan2
- MYO1B | c.541C>T p.L181= | Silent (SNP) | VAF 132/296 reads (45%) | called by muse, varscan2
- NPIPB2 | c.1095A>G p.E365= (on ENST00000399147; = p.E225= on NM_001355514.1) | Silent (SNP) | VAF 88/772 reads (11%) | catalogued as rs79845530, COSV63638523; called by muse, varscan2
- PKHD1L1 | c.6564A>G p.G2188= | Silent (SNP) | VAF 173/396 reads (44%) | catalogued as rs769223422, COSV65737892; called by mutect2, varscan2
- RB1CC1 | c.1677C>A p.P559= | Silent (SNP) | VAF 169/386 reads (44%) | called by muse, mutect2, varscan2
- RBM45 | c.306C>T p.F102= | Silent (SNP) | VAF 151/304 reads (50%) | called by muse, mutect2, varscan2
- SETBP1 | c.4164G>A p.S1388= | Silent (SNP) | VAF 319/497 reads (64%) | catalogued as rs773446890, COSV56320238; called by muse, mutect2, varscan2
- SHROOM3 | c.3210G>A p.T1070= | Silent (SNP) | VAF 467/984 reads (47%) | called by muse, mutect2, varscan2
- SYT16 | c.1038G>A p.E346= | Silent (SNP) | VAF 232/508 reads (46%) | called by muse, mutect2, varscan2
- MACF1 | c.15832-8796A>G | Intron (SNP) | VAF 92/1186 reads (8%) | catalogued as rs783822, COSV57106096; called by muse, varscan2
- MUC2 | chr11:1094639 del C | 3'Flank (DEL) | VAF 24/411 reads (6%) | called by mutect2, varscan2*
- ZNF692 | c.-12-165A>G | Intron (SNP) | VAF 251/553 reads (45%) | called by muse, mutect2, varscan2
